Somatic mutation profile of tumor specimen MP2PRT-PAVDZD-TMP1-A (aliquot MP2PRT-PAVDZD-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVDZD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,080 days).
Specimen MP2PRT-PAVDZD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65800cd3-2bb5-4603-9544-9061b5840eb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVDZD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVDZD-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1849b8d9-7f22-4a9d-a005-285fb21040d3

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Intron 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397507509, CD041931, CM021126, CX060726, COSV100692385, COSV61005028, COSV61006397; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CNGB1 | c.585G>A p.A195= | Splice Region (SNP) | VAF 97/354 reads (27%) | catalogued as rs530319460, COSV99202304; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNND2 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761131174; called by muse, mutect2
- GFRA1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 37/717 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs376230694; called by muse, mutect2
- HYDIN | c.14605C>T p.R4869W | Missense Mutation (SNP) | VAF 35/580 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs748062821; called by muse, mutect2
- KIT | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 49/326 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs754400702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LDHD | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 58/668 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs199941890; called by muse, mutect2
- MMRN1 | c.2615C>T p.T872M | Missense Mutation (SNP) | VAF 69/380 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs774204805, COSV53333894, COSV53336592; called by muse, mutect2
- MUC6 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 107/428 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs755046915, COSV70146958; called by muse, varscan2
- OR52L1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs763535932, COSV59989257; called by muse, mutect2
- PCDHB12 | c.829C>A p.L277I | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs781840216; called by muse, mutect2, varscan2
- PHF21B | c.589C>G p.P197A | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs780934755; called by muse, mutect2, varscan2
- PPEF1 | c.1790T>A p.L597H | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62995120; called by muse, mutect2, varscan2
- CCL19 | c.61A>G p.S21G | Missense Mutation (SNP) | VAF 63/303 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP46 | c.4678G>T p.A1560S | Missense Mutation (SNP) | VAF 72/519 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP47 | c.6950A>C p.Q2317P | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- DYDC2 | c.141del p.E48Kfs*23 | Frame Shift Del (DEL) | VAF 36/277 reads (13%) | called by mutect2, varscan2
- MMADHC | c.112G>C p.G38R | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- PLG | c.2010G>T p.K670N | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RGS5 | c.35T>A p.I12N | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A9 | c.1697T>A p.F566Y (on ENST00000360584 / NM_201649.4; = p.F512Y on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTN | c.16202G>T p.S5401I (on ENST00000591111; = p.S4474I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/345 reads (8%) | PolyPhen benign (0.037); called by muse, mutect2
- UBTF | c.1158G>T p.Q386H | Missense Mutation (SNP) | VAF 86/430 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- CDR1 | c.327G>A p.P109= | Silent (SNP) | VAF 111/389 reads (29%) | catalogued as rs775755335, COSV65164056; called by muse, mutect2, varscan2
- DNAH14 | c.691T>C p.L231= (on ENST00000445597; = p.L54= on NM_144989.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs770907275; called by muse, mutect2
- IGHG4 | c.843C>T p.D281= | Silent (SNP) | VAF 96/862 reads (11%) | catalogued as rs758157147; called by muse, mutect2, varscan2
- MAPK8IP2 | c.2406C>T p.R802= | Silent (SNP) | VAF 88/252 reads (35%) | catalogued as rs1035051920; called by muse, varscan2
- NPTN | c.642C>T p.G214= | Silent (SNP) | VAF 82/217 reads (38%) | catalogued as COSV54737022; called by muse, mutect2, varscan2
- OR2T12 | c.822C>T p.A274= | Silent (SNP) | VAF 29/225 reads (13%) | catalogued as COSV58776821; called by muse, mutect2, varscan2
- PGC | c.1041C>T p.V347= | Silent (SNP) | VAF 62/277 reads (22%) | catalogued as rs767505632, COSV57823945; called by muse, mutect2, varscan2
- SCN2A | c.4134C>T p.S1378= | Silent (SNP) | VAF 35/334 reads (10%) | catalogued as rs145465905, COSV99334204; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- KCNAB1 | c.275+22493G>A | Intron (SNP) | VAF 21/226 reads (9%) | catalogued as rs376161842; called by muse, mutect2, varscan2
